Somatic mutation profile of tumor specimen TCGA-VQ-A8E7-01B (aliquot TCGA-VQ-A8E7-01B-11D-A410-08) from TCGA case TCGA-VQ-A8E7, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 59.3 years (21,664 days).
Specimen TCGA-VQ-A8E7-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbaac195-6a3c-44b6-b296-3e0db252f900.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8E7-10B (Blood Derived Normal), aliquot TCGA-VQ-A8E7-10B-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a26fcdb5-af83-4708-a5a5-ce48660f1679

The open-access MAF lists 109 somatic variants for this specimen: 73 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 34, Nonsense Mutation 6, Frame Shift Ins 2, RNA 2, Frame Shift Del 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB4 | c.2393T>G p.L798R | Missense Mutation (SNP) | VAF 51/73 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725903, COSV61483358, COSV61493836; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 29/51 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2719G>A p.V907I | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.157); catalogued as rs573245329, COSV55962155; called by muse, mutect2, varscan2
- ACAD8 | c.1092C>T p.A364= | Splice Region (SNP) | VAF 9/18 reads (50%) | catalogued as rs146813391, COSV55539207, COSV99844069; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACE2 | c.604T>C p.Y202H | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99382564; called by muse, mutect2, varscan2
- ADAMTS13 | c.2859T>C p.A953= | Splice Region (SNP) | VAF 8/26 reads (31%) | catalogued as rs1554793368, COSV100746960; called by muse, mutect2
- C6orf118 | c.1403G>T p.R468I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.262); catalogued as COSV100024141; called by muse, mutect2, varscan2
- CCN3 | c.137C>A p.T46K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1259008749, COSV99422745; called by muse, mutect2, varscan2
- CDH11 | c.1179A>C p.Q393H | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV51770394, COSV99217327; called by muse, mutect2, varscan2
- CDK11B | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100477312; called by muse, mutect2, varscan2
- CFHR1 | c.502T>G p.S168A | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV100258649; called by muse, mutect2, varscan2
- CNPY4 | c.480G>C p.L160F | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99498751; called by muse, mutect2
- CNTNAP2 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV100663015, COSV62211693; called by muse, mutect2, varscan2
- CSPG4 | c.5759G>A p.S1920N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs1177341499, COSV100413464; called by muse, mutect2, varscan2
- DISC1 | c.1808C>T p.T603M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as rs148111679, CM080195, COSV54407026; called by muse, mutect2, varscan2
- DISP3 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV99607435; called by muse, mutect2, varscan2
- DLD | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 82/157 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52737271; called by muse, mutect2, varscan2
- EPHX4 | c.515dup p.M173Hfs*12 | Frame Shift Ins (INS) | VAF 50/172 reads (29%) | catalogued as rs765115164; called by mutect2, varscan2
- FAT2 | c.2882G>A p.R961Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs775693755, COSV55826484; called by muse, mutect2, varscan2
- FBP2 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 45/97 reads (46%) | catalogued as rs376093116; called by muse, mutect2, varscan2
- FHOD3 | c.3047A>G p.Q1016R (on ENST00000359247 / NM_001281739.3; = p.Q1033R on NM_025135.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1298897588, COSV99940234; called by muse, mutect2, varscan2
- GRIA1 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV53616738; called by muse, mutect2, varscan2
- IRAK3 | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV99705916; called by muse, mutect2, varscan2
- KCNG1 | c.1332C>A p.S444R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100856991; called by muse, mutect2, varscan2
- KLK8 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs371793414; called by muse, mutect2, varscan2
- LCP2 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.477); catalogued as rs1169444539, COSV99252137; called by muse, mutect2
- LIG4 | c.2157T>A p.D719E | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100799714; called by muse, mutect2, varscan2
- LRRC15 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs767913133, COSV61650256; called by muse, mutect2, varscan2
- MAP3K8 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV99551953; called by muse, mutect2, varscan2
- MEFV | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs775663363, COSV99560307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPL14 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 88/271 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100921027; called by muse, mutect2, varscan2
- MUC16 | c.39232G>C p.G13078R | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.009); catalogued as COSV101109626; called by muse, mutect2, varscan2
- MUC16 | c.3340A>C p.T1114P | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as rs1371349932, COSV101198316; called by muse, mutect2, varscan2
- MUTYH | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100587911; called by muse, varscan2
- OR4K2 | c.493A>C p.T165P | Missense Mutation (SNP) | VAF 63/352 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV100064118; called by muse, mutect2, varscan2
- OSBP | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs765435028, COSV55661339; called by muse, mutect2, varscan2
- OSBP2 | c.1580T>C p.M527T | Missense Mutation (SNP) | VAF 84/124 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs892969852, COSV100212672; called by muse, mutect2, varscan2
- PAX3 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 78/145 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100399093; called by muse, mutect2, varscan2
- PCDHA9 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs572249977, COSV65324558; called by muse, mutect2, varscan2
- PDPN | c.460C>T p.R154* (on ENST00000621990; = p.R230* on NM_006474.4) | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as rs370056113; called by muse, mutect2, varscan2
- PKP4 | c.118T>G p.S40A | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV101080258; called by muse, mutect2, varscan2
- POGLUT2 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV101050760; called by muse, mutect2, varscan2
- POT1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs587777476, CM144554, COSV62932457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PROX1 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99798728; called by muse, mutect2, varscan2
- PTPRU | c.3272G>A p.R1091H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs939145772, COSV100111777; called by muse, mutect2, varscan2
- RESF1 | c.4964T>C p.V1655A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs372445970, COSV100440112; called by muse, mutect2, varscan2
- RRP36 | c.768G>C p.L256F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV55064220; called by muse, mutect2, varscan2
- RUNDC3B | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.363); catalogued as rs750107326, COSV55949678, COSV55956462; called by muse, varscan2
- SACS | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV101207196; called by muse, mutect2, varscan2
- SCUBE2 | c.1650C>G p.S550R | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.255); catalogued as COSV100496338; called by muse, mutect2, varscan2
- SEC31B | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs369775036, COSV100947213; called by muse, mutect2, varscan2
- SLC17A6 | c.1501G>T p.E501* | Nonsense Mutation (SNP) | VAF 57/79 reads (72%) | catalogued as rs760965326, COSV99580827; called by muse, mutect2, varscan2
- SLC2A14 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100533554; called by muse, mutect2, varscan2
- SORBS2 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs548721156, COSV99509617; called by muse, mutect2, varscan2
- SPTA1 | c.4218A>T p.Q1406H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100934336; called by muse, mutect2, varscan2
- SRD5A2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as COSV99252225; called by muse, mutect2, varscan2
- SSX5 | c.215G>A p.R72H (on ENST00000347757 / NM_175723.1; = p.R113H on NM_021015.4) | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs149409740, COSV61255238; called by muse, mutect2, varscan2
- TAF1L | c.4427C>T p.A1476V | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs752878173, COSV99644155; called by muse, mutect2, varscan2
- TMEM132D | c.636G>T p.R212S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1377046137, COSV70612495; called by muse, mutect2, varscan2
- TTC14 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 26/101 reads (26%) | catalogued as COSV99931834; called by muse, mutect2, varscan2
- WNK1 | c.6289G>A p.E2097K (on ENST00000315939 / NM_018979.4; = p.E1849K on NM_014823.3) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100266296; called by muse, mutect2, varscan2
- XPO1 | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT tolerated (0.48); PolyPhen benign (0.333); catalogued as COSV101294163; called by muse, mutect2, varscan2
- ZDHHC22 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1336186284, COSV100083665; called by muse, mutect2
- ZNF462 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs538337965, COSV99470857; called by muse, mutect2, varscan2
- ZNF614 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 57/207 reads (28%) | catalogued as rs78398086, COSV54544916; called by muse, mutect2, varscan2
- ZNF667 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV99410063; called by muse, mutect2, varscan2
- ZNF676 | c.1163A>C p.K388T (on ENST00000650058; = p.K356T on NM_001001411.3) | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68092723; called by muse, varscan2
- ZNF684 | c.952C>A p.Q318K | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.043); catalogued as COSV101015915; called by muse, mutect2, varscan2
- ZNF99 | c.1609T>C p.Y537H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101233722; called by muse, varscan2
- HSPA4L | c.2173del p.R725Dfs*21 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- IGKV1D-13 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by mutect2, varscan2
- MTMR12 | c.306_310del p.K102Nfs*5 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- PPIB | c.144dup p.D49* | Frame Shift Ins (INS) | VAF 47/175 reads (27%) | called by mutect2, pindel, varscan2
- AMOT | c.1437C>T p.L479= (on ENST00000371959 / NM_001113490.1; = p.L70= on NM_133265.3) | Silent (SNP) | VAF 48/66 reads (73%) | catalogued as rs184493349, COSV100494759; called by muse, mutect2, varscan2
- ART3 | c.1092C>A p.G364= (on ENST00000355810 / NM_001377173.1; = p.G353= on NM_001179.6) | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99345158; called by muse, mutect2
- ASTN2 | c.1218C>T p.D406= (on ENST00000313400 / NM_001365069.1; = p.D355= on NM_014010.5) | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs373796089; called by muse, mutect2, varscan2
- BIRC7 | c.414C>T p.D138= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs776404641, COSV53903191; called by muse, mutect2, varscan2
- C1orf21 | c.300C>T p.F100= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99334086; called by muse, mutect2, varscan2
- CDH4 | c.2691C>T p.N897= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs1034077889, COSV64641501; called by muse, mutect2, varscan2
- CPNE7 | c.1779G>A p.A593= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as rs948203242, COSV52013632; called by muse, mutect2, varscan2
- DIDO1 | c.4554C>T p.D1518= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs756935492, COSV56627028; called by muse, mutect2, varscan2
- DRD4 | c.1200C>T p.Y400= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs1295609209, COSV99448452; called by muse, mutect2, varscan2
- DSG1 | c.78A>T p.R26= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99935606; called by muse, mutect2, varscan2
- INSR | c.723C>A p.G241= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV100251520; called by muse, mutect2, varscan2
- KIF11 | c.747G>A p.T249= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs997248301, COSV99585660; called by muse, mutect2, varscan2
- LATS2 | c.3078C>T p.T1026= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as rs769023154, COSV101231476; called by muse, mutect2, varscan2
- MUTYH | c.216G>A p.V72= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100587913; called by muse, varscan2
- PCDH18 | c.1623C>T p.I541= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as rs1362447883, COSV100787057; called by muse, mutect2, varscan2
- PRKAR1B | c.75C>T p.H25= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV100816536, COSV64318378; called by muse, mutect2, varscan2
- PSKH2 | c.165C>T p.F55= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1410438448, COSV52612035; called by muse, mutect2, varscan2
- PTGDS | c.72G>A p.P24= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs756456741, COSV99811718; called by muse, mutect2, varscan2
- RFTN1 | c.1065C>A p.I355= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV61918082; called by muse, mutect2, varscan2
- RPGRIP1 | c.2748C>T p.N916= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs907727614, COSV99250500; called by muse, mutect2, varscan2
- RPTOR | c.3987G>A p.S1329= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs769703866, COSV60803408; called by muse, mutect2, varscan2
- SEMA4D | c.1572G>A p.P524= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs142877769; called by muse, mutect2, varscan2
- SFMBT2 | c.1845C>T p.I615= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as rs773641504, COSV62812212; called by muse, mutect2, varscan2
- SLC52A2 | c.1164C>T p.Y388= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs370533575; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNTB1 | c.888C>T p.N296= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs780898987, COSV101179783; called by muse, mutect2, varscan2
- SVEP1 | c.3348G>A p.S1116= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs369614705; called by muse, varscan2
- TMEM169 | c.546C>T p.Y182= | Silent (SNP) | VAF 48/89 reads (54%) | catalogued as rs773725400, COSV55264328; called by muse, mutect2, varscan2
- TNFAIP2 | c.1629C>T p.A543= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs202219293, COSV100280834; called by muse, mutect2, varscan2
- TNRC18 | c.8523C>A p.I2841= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100078566; called by muse, mutect2, varscan2
- TSC2 | c.585C>T p.I195= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs397515309; ClinVar: likely benign; called by muse, mutect2, varscan2
- WHAMM | c.1797G>A p.S599= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs762912777, COSV54495017; called by muse, mutect2, varscan2
- ZCCHC9 | c.540A>G p.E180= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV99562600; called by muse, mutect2
- ZNF577 | c.213G>T p.S71= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100030788, COSV56817765; called by muse, mutect2, varscan2
- ZNF831 | c.1758C>T p.D586= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs968436868, COSV64036891, COSV64041705; called by muse, mutect2, varscan2
- C12orf77 | n.520G>A | RNA (SNP) | VAF 18/47 reads (38%) | catalogued as rs760233113; called by muse, mutect2, varscan2
- IGKV1-13 | n.284C>A | RNA (SNP) | VAF 44/241 reads (18%) | called by muse, mutect2, varscan2
